CCDI case PBBUEV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/a56c9c4a-7bc9-4fb2-b3fc-99dc8711d832

Demographics
Sex at birth: male.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Anterior wall of nasopharynx; Age at diagnosis: 10.1 years (3,702 days).

Biospecimens (4 samples)
- Sample 0DHKP3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DHKQ6, 0DHKQC (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DITTW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
